Somatic mutation profile of tumor specimen TARGET-30-PASFGG-01A (aliquot TARGET-30-PASFGG-01A-01D) from TARGET case TARGET-30-PASFGG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.8 years (1,037 days).
Specimen TARGET-30-PASFGG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bc0f166-4b7d-443a-b573-8cc194dc5a5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASFGG-10A (Blood Derived Normal), aliquot TARGET-30-PASFGG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18a1494e-9b7d-48d1-9b96-cd0917aebc91

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRNKL1 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV55648610; called by muse, mutect2, varscan2
- GORASP1 | c.1270G>T p.G424W | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); catalogued as COSV56534566; called by muse, mutect2, varscan2
- LRRN1 | c.802T>G p.L268V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1166248909, COSV60015931; called by muse, mutect2, varscan2
- NFATC1 | c.1959G>A p.P653= | Splice Region (SNP) | VAF 15/51 reads (29%) | catalogued as rs1013516921, COSV53710014; called by muse, mutect2, varscan2
- OR14J1 | c.768G>T p.E256D | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV65845988; called by muse, mutect2, varscan2
- TRAF3IP2 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV60677468; called by muse, mutect2, varscan2
- USP6NL | c.1432A>C p.N478H | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV53216038; called by muse, mutect2, varscan2
- ELOA3B | c.857C>A p.S286Y | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- DCT | c.444G>A p.A148= | Silent (SNP) | VAF 38/222 reads (17%) | catalogued as COSV65467396; called by muse, mutect2, varscan2
- FBXO10 | c.9T>C p.A3= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1490781885; called by muse, mutect2
- PSENEN | c.87C>A p.L29= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as COSV53076801; called by muse, mutect2, varscan2
- RNF125 | c.159C>A p.G53= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV54187024; called by muse, mutect2, varscan2
- UPK1B | c.255G>A p.R85= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs868042875, COSV51767043; called by muse, mutect2, varscan2
- VAV3 | c.69G>A p.V23= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV64072496; called by muse, mutect2, varscan2
